TCGA case TCGA-MM-A563 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: BLN - Baylor. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fe1f95a3-a6c2-4a39-8586-f8a70e975dd4

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 41 years; Vital status: Alive.

Diagnoses (1)
1. Clear cell adenocarcinoma, NOS: ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 41.2 years (15,037 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3; AJCC pathologic N: NX; AJCC pathologic M: MX; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 268 days; Disease response: Tumor Free.
- Days to follow up: 591 days (1.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Leukocytes: Normal.
- Platelets: Normal.
- Calcium: Normal.
- Hemoglobin: Normal.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 14; Tobacco smoking onset year: 1999.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-MM-A563-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 220 mg.
  Slide TCGA-MM-A563-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 100; Percent neutrophil infiltration: 0.
- Sample TCGA-MM-A563-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-MM-A563-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Lymph nodes examined: No; Tobacco smoking history indicator: 2; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- New tumor event: New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Stable Disease; New tumor event diagnosis indicator: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 591 days; disease-specific survival: no event (censored), 591 days; disease-free interval: no event (censored), 591 days; progression-free interval: no event (censored), 591 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-MM-A563-01A-11D-A25U-01): tumor purity 0.64, ploidy 1.77, whole-genome doublings 0.
